Surgical pathology report (de-identified scan), TCGA case TCGA-CM-5868, project TCGA-COAD (Colon Adenocarcinoma), tissue source site MSKCC, specimen TCGA-CM-5868-01A (Primary Tumor).

[page 1 of 6]
Clinical Diagnosis & History:

with metastatic sigmoid carcinoma here for sigmoid resection and IHAP placement.

Specimens Submitted:

- 1: SP: Sigmoid colon, resection
- 2: SP: Gallbladder, excision
- 3: SP: Lymph node of callot, excision
- 4: SP: Hepatic artery lymph node, excision
- 5: SP: Left fallopian tube and ovary, excision
- 6: SP: Right fallopian tube and ovary, excision
- 7: SP: Proximal ring, excision
- 8: SP: Distal ring, excision

DIAGNOSIS:

1. SP: Sigmoid colon, resection:

Tumor Type:

Adenocarcinoma

Histologic Grade:

Moderately differentiated

Tumor Location:

Sigmoid colon

Tumor Size:

Length is 5 cm

Width is 4.5 cm

Maximal thickness is 2.0 cm

Tumor Budding:

Extensive

Increased Tumor Infiltrating Lymphocytes:

Absent

Precursor Lesions:

Tubular adenoma

Deepest Tumor Invasion:

Serosal surface

Gross Tumor Perforation:

Not identified

Lymphovascular Invasion:

Suspected

Large Venous Invasion:

Identified

** Continued on next page **

[page 2 of 6]
Perineural Invasion:

Identified

Surgical Margins:

Free of tumor

Polyps/Mucosa Dysplasia (away from the carcinoma):

Not Identified

Non-Neoplastic Bowel:

Unremarkable

Lymph Nodes:

Number with metastasis: 1

Total number examined: 17

Tumor deposits in pericorectal soft tissue:

Identified

Tumor Staging (AJCC 7th Edition):

pT4a (Tumor penetrates to the surface of the visceral peritoneum)

Lymph Node Stage (AJCC 7th Edition):

N1 (Metastasis in 1-3 regional lymph nodes)

2. SP: Gallbladder, cholecystectomy:

- Gall bladder with chronic inflammation and cholelithiasis.

3. SP: Lymph node of callot, excision:

-One benign lymph node (0/1).

4. SP: Hepatic artery lymph node, excision:

-One benign lymph node (0/1).

5. SP: Left fallopian tube and ovary, excision:

-Benign fallopian tube and ovary.

6. SP: Right fallopian tube and ovary, excision:

-Benign ovary and fallopian tube with paratubal cyst.

7. SP: Colon, proximal ring, excision:

-Benign colonic tissue.

8. SP: Colon, distal ring, excision:

-Benign colonic tissue.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

Gross Description:

1).The specimen is received fresh and is labeled "sigmoid colon". It consists of a sigmoid colon that measures 9 cm in length and 2.5 cm in

** Continued on next page **

[page 3 of 6]
----- Page 3 of 6
average diameter. The serosal surface is tan-pink smooth and glistening with two focal puckered regions both 0.3 CM in greatest dimension. The radial resection margin is inked blue and the specimen is opened to reveal a tumor that is located 10 cm from the proximal margin and five cm from the distal margin. The tumor measures five cm in length and 4.5 cm in width. Serial sectioning reveals an ulcerating tumor invading through the bowel wall into the pericolonic fat and extending to the puckered serosa, to a depth of 2 cm, which is 4 cm from the closest radial margin. The remaining mucosa shows normal folds and no gross abnormality. Pericolonic and peri-colonic adipose tissue is submitted for lymph node dissection, and all possible nodes are submitted. Representative sections are submitted. TPS is submitted.

Summary of sections:

PM - proximal margin

DM - distal margin

RM - radial margin

T - tumor

PLN-grossly positive lymph nodes subjacent to tumor

U - uninvolved mucosa

LN - lymph nodes

BLN-bisected lymph nodes

2). The specimen is received fresh, labeled "Gallbladder" and consists of a green and purple gallbladder measuring 8.2 x 4.2 x 2.5cm. The surface of the gallbladder is green purple and smooth. It is opened to reveal two black green angulated granular calculi measuring 1.4 cm and 1.5 cm in greatest dimension, with green black viscid bile. It also reveals a green yellow velvety mucosa with a wall measuring up to 0.2 cm. Representative sections including the cystic duct margin are submitted.

Summary of sections:

M - cystic duct margin

G - undesignated

3). The specimen is received in formalin, labeled "Lymph node of callot" and consists of a single lymph node measuring 2.3 x 1.4 x 0.8 cm. The lymph node is bisected and entirely submitted.

Summary of sections:

LN - lymph node

4). The specimen is received in formalin, labeled "Hepatic artery lymph node" and consists of a single lymph node measuring 3.8 x 1.8 x 1.0 cm. The lymph node is sectioned and entirely submitted.

** Continued on next page **

[page 4 of 6]
Summary of sections:

LN - lymph node

5). The specimen is received in formalin, labeled "Left fallopian tube and ovary" and consists of a fallopian tube with attached ovary. The fallopian tube measures 2.5 cm in length and averages 0.8 cm in diameter. The external surface of the tube is pink tan and smooth with a normal fimbriated end. Cut section through the tube reveals a pinpoint lumen. The attached ovary measures 2.5 x 1.7 x 1.0 cm. The external surface is white-tan and cerebriform. Cut section through the ovary reveals a white-tan appearance. Representative sections are submitted.

Summary of sections:

F - fallopian tube

O - ovary

6). The specimen is received in formalin, labeled "Right fallopian tube and ovary" and consists of a fallopian tube with attached ovary. The fallopian tube measures 2.5 cm in length and averages 0.6 cm in diameter. The external surface of the tube is pink tan and smooth with a normal fimbriated end. There are several paratubal cysts identified which measure up to 0.4 x 0.3 cm in greatest dimensions. Cut section through the tube reveals a pinpoint lumen. The attached ovary measures 2.5 x 2 x 1.0 cm. The external surface is white-tan and smooth. Cut section through the ovary reveals a white-tan appearance. Representative sections are submitted.

Summary of sections:

F - fallopian tube

O - ovary

7). The specimen is received in formalin wrapped around an anastomotic pin, labeled "Proximal ring" and consists of a ring of pink tan soft tissue measuring 1.8 x 1.8 x 1.0 cm. Multiple sutures and staples are attached. The mucosal surface is pink tan and focally hemorrhagic. The sutures and staples are removed and the soft tissue is entirely submitted.

Summary of sections:

U - undesignated

8). The specimen is received in formalin, labeled "Distal ring" and consists of a ring of pink tan soft tissue measuring 2.5 x 2.5 x 1.5 cm. Multiple sutures and staples are attached. The mucosal surface is pink tan and focally hemorrhagic. The sutures and staples are removed and the soft tissue is entirely submitted.

Summary of sections:

U - undesignated

** Continued on next page **

[page 5 of 6]
Summary of Sections:

Part 1: SP: Sigmoid colon, resection

Block	Sect. Site	PCs
1	DM	1
7	LN	16
3	PLN	3
1	PM	1
1	RM	1
5	T	5
1	U	1

Part 2: SP: Gallbladder, excision

Block	Sect. Site	PCs
1	G	1
1	M	1

Part 3: SP: Lymph node of callot, excision

Block	Sect. Site	PCs
1	ln	1

Part 4: SP: Hepatic artery lymph node, excision

Block	Sect. Site	PCs
2	ln	2

Part 5: SP: Left fallopian tube and ovary, excision

Block	Sect. Site	PCs
1	f	1
1	o	1

Part 6: SP: Right fallopian tube and ovary, excision

Block	Sect. Site	PCs
1	f	1
1	o	1

Part 7: SP: Proximal ring, excision

Block	Sect. Site	PCs
1	u	1

Part 8: SP: Distal ring, excision

Block	Sect. Site	PCs
1	u	1

** Continued on next page **

[page 6 of 6]
CONFIDENTIAL

----- Page 6 of 6

** End of Report **

Source: NCI Genomic Data Commons file 99f33172-22ac-4954-a73c-0fcecafc1628 (TCGA-CM-5868.F5259A76-974F-483B-A980-CB39B45FD791.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).